Gene-level copy-number profile of tumor specimen TCGA-FV-A3I1-01A from TCGA case TCGA-FV-A3I1, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2.
Specimen TCGA-FV-A3I1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.3de0c929-c00f-4d5f-a484-456325ab11e7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FV-A3I1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5b46d051-58a7-4692-9892-35e8479700c7

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 74; copy number 1: 659; copy number 2: 6,253; copy number 3: 5,953; copy number 4: 40,851; copy number 5: 1,518; copy number 6: 4,088; copy number 7: 167; copy number 9: 191; copy number 16: 8; copy number 17: 15; copy number 24: 40.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FV-A3I1-01A-11D-A22E-01): tumor purity 0.69, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 74 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:79,492,704–79,649,359, 5 genes: CTNNA2-AS1, AC010975.1, GNA13P1, RNU6-561P, MIR4264.
- chr2:116,687,218–116,726,771, 2 genes: AC104408.1, AC062016.1.
- chr2:140,586,626–140,683,888, 2 genes: MIR7157, COPRSP1.
- chr9:21,135,598–23,898,054, 65 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 254 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:45,574,140–45,843,740, 8 genes, copy number 16 (within-gene range 2–16): ADCY1, SEPTIN7P2, GTF2IP13, RNU6-241P, CICP20, AC096582.1, AC096582.2, RNU6-326P.
- chr7:57,067,950–57,485,895, 40 genes, copy number 24: AC122133.1, ZNF479, AC099654.11, AC099654.2, AC099654.5, AC099654.8, MTATP6P8, MTCO3P10, AC099654.4, MTND4LP32, MTND4P4, MTND5P6, MTND6P29, MTCYBP29, GUSBP10, MTND1P4, MTND2P6, MTCO1P10, MTCO2P10, AC099654.6, MTATP6P10, MTCO3P4, AC099654.9, AC099654.7, MTND4P5, MTND5P7, AC099654.10, MTCYBP5, GUSBP12, AC099654.1, RNU7-157P, AC099654.12, AC099654.3, AC237221.2, AC237221.1, MIR3147, VN1R28P, SAPCD2P2, ZNF716, AC092175.1.
- chr8:110,555,408–127,419,050, 191 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr19:15,235,519–15,584,709, 15 genes, copy number 17 (within-gene range 2–17): BRD4, AC005776.1, AC005776.2, AKAP8, AC005785.1, AKAP8L, AC005785.2, AC006128.1, WIZ, MIR1470, RASAL3, PGLYRP2, CYP4F22, AC011492.1, CYP4F23P.

Autosomal genes at a single copy (total copy number 1): 659. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
